Somatic mutation profile of tumor specimen 0DDVSI from CCDI case PBBPEP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Synovial sarcoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 9.3 years (3,407 days).
Specimen 0DDVSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd1e4310-b7db-4635-9587-e397ce49fba6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDVSR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c32ef76c-82a2-4bfc-b170-869629124d1b

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LLGL2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 20/622 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs1408799294; called by muse, mutect2
- REXO1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 165/355 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as COSV50074994; called by muse, mutect2, varscan2
- RPAP2 | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 569/1301 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72101478; called by muse, mutect2, varscan2
- TTC13 | c.950T>C p.I317T | Missense Mutation (SNP) | VAF 444/1127 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as rs1016731811, COSV100793010; called by muse, mutect2, varscan2
- EBF4 | c.1009G>A p.V337I (on ENST00000609451; = p.V333I on NM_001110514.1) | Missense Mutation (SNP) | VAF 42/692 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- HSF4 | c.1228A>G p.M410V (on ENST00000521374 / NM_001040667.3; = p.M380V on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 422/1010 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNH1 | c.2471C>T p.P824L (on ENST00000271751 / NM_172362.3; = p.P797L on NM_002238.4) | Missense Mutation (SNP) | VAF 299/875 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCA2 | c.2834T>C p.F945S | Missense Mutation (SNP) | VAF 370/1244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOK5 | c.402A>G p.E134= | Silent (SNP) | VAF 273/663 reads (41%) | catalogued as rs201026396; called by muse, mutect2, varscan2
- MYO16 | c.153G>A p.A51= | Silent (SNP) | VAF 75/1306 reads (6%) | catalogued as rs749546658, COSV51805323; called by muse, mutect2
- HNRNPA1L2 | c.*44C>G | 3'UTR (SNP) | VAF 16/590 reads (3%) | called by muse, mutect2
- TTC16 | c.1764+15G>A | Intron (SNP) | VAF 138/609 reads (23%) | called by muse, mutect2, varscan2
